Surgical pathology report (de-identified scan), TCGA case TCGA-HQ-A5NE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HQ-A5NE-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	invasive transitional cell (urothelial) carcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	Resection - radical cystoprostatectomy
Site of Tissue/Primary (Histology)	Bladder
Tumour Size (cm)	4
Histology	invasive transitional cell (urothelial) carcinoma
Grade/Differentiation	III
Pathological T	T3
Pathological N	N0
Clinical M	M0
Histology Comments	

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3

Carcinoma, urothelial NOS 8120/3
Site: Bladder NOS C67.9
JW 2/11/13

Dual/Sync. Incons. Primary Noted		

Source: NCI Genomic Data Commons file 47162090-af50-4338-b00e-4f462f1449dc (TCGA-HQ-A5NE.464FAAEC-5FEB-4544-8B28-46559A81A09A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).